Somatic mutation profile of tumor specimen C3N-01715-02 (aliquot CPT0125090006_1) from CPTAC case C3N-01715, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 61.7 years (22,534 days).
Specimen C3N-01715-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 178eb3de-bf7b-4fb1-8aa1-8d49a405b12d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01715-31 (Blood Derived Normal), aliquot CPT0125120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b9c0087-f173-4bc1-b0ff-55b12f523ff9

The open-access MAF lists 935 somatic variants for this specimen: 615 protein-altering or splice-affecting, 193 silent, 127 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 428, Silent 193, Frame Shift Del 85, Intron 60, Frame Shift Ins 35, 3'UTR 26, In Frame Del 21, Nonsense Mutation 19, 5'UTR 18, Splice Region 16, Splice Site 10, 5'Flank 9.

Variants (750 of 935; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5039_5041del p.S1680del | In Frame Del (DEL) | VAF 148/1317 reads (11%) | hotspot (GDC flag); catalogued as rs587783502; called by pindel, varscan2
- KMT2D | c.8488C>T p.R2830* | Nonsense Mutation (SNP) | VAF 171/685 reads (25%) | catalogued as rs727503983, CM105465, COSV56427366; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MLH1 | c.350C>G p.T117R | Missense Mutation (SNP) | VAF 54/508 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs63750781, CM950802, CM960965, COSV51617070; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYO15A | c.1185del p.E396Rfs*48 | Frame Shift Del (DEL) | VAF 110/1012 reads (11%) | catalogued as rs772536599; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MYO7A | c.397del p.H133Tfs*13 | Frame Shift Del (DEL) | VAF 52/558 reads (9%) | catalogued as rs111033187; ClinVar: likely pathogenic; called by mutect2, pindel
- PNPLA6 | c.2813G>A p.R938H (on ENST00000414982 / NM_001166111.2; = p.R890H on NM_006702.5) | Missense Mutation (SNP) | VAF 74/536 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as rs121434416, CM081403, COSV55378349; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1996A>G p.K666E | Missense Mutation (SNP) | VAF 88/690 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs754688962, COSV59206172, COSV59206856; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 38/514 reads (7%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by muse, mutect2
- ABCA8 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs139423903; called by muse, varscan2
- ABCB1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 64/704 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1429920034; called by muse, mutect2
- ABO | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 178/1476 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.311); catalogued as rs782721438, COSV101505925, COSV71743460; called by mutect2, varscan2
- ACAD11 | c.1414+6T>C | Splice Region (SNP) | VAF 16/188 reads (9%) | catalogued as rs373234442; called by muse, mutect2
- ACAD8 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 104/1078 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371449613, CM063825; ClinVar: uncertain significance; called by muse, mutect2
- ACKR3 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 77/611 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs565164449, COSV56021394; called by muse, mutect2, varscan2
- ADAM33 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 50/473 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as rs1216058743; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2372C>T p.T791M | Missense Mutation (SNP) | VAF 41/469 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.509); catalogued as rs144077662, COSV54450723; called by muse, mutect2
- ADCK5 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs782320085; called by muse, mutect2, varscan2
- ADGRG4 | c.5812T>A p.S1938T | Missense Mutation (SNP) | VAF 53/402 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as rs758897711, COSV54951044; called by muse, mutect2, varscan2
- ADHFE1 | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 165/498 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.103); catalogued as rs376645357; called by muse, mutect2, varscan2
- ADSS1 | c.741del p.K248Rfs*23 | Frame Shift Del (DEL) | VAF 24/190 reads (13%) | catalogued as rs769542442; called by mutect2, pindel, varscan2
- AEBP2 | c.66dup p.G23Rfs*12 | Frame Shift Ins (INS) | VAF 70/721 reads (10%) | catalogued as rs1555180802; called by mutect2, pindel
- AGBL1 | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 30/189 reads (16%) | catalogued as rs544094832, COSV66849419; called by muse, mutect2
- AIP | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 130/1142 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.024); catalogued as rs139947406; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG1 | c.1223T>C p.L408P | Missense Mutation (SNP) | VAF 91/868 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770775485; called by muse, mutect2, varscan2
- ANK2 | c.5426C>T p.A1809V | Missense Mutation (SNP) | VAF 45/341 reads (13%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs531261130, COSV52148371; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD9 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 62/380 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1318434677; called by muse, mutect2, varscan2
- ANKS1B | c.3265C>T p.R1089W (on ENST00000547776 / NM_152788.4; = p.R255W on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1410929626, COSV59115659; called by muse, mutect2
- ANTXR1 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 117/893 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58009595; called by muse, mutect2, varscan2
- AOC2 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 62/882 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs267604890, COSV53827971; called by muse, mutect2
- APP | c.302G>A p.G101D | Missense Mutation (SNP) | VAF 66/566 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.603); catalogued as rs532382285, COSV100695946; called by muse, mutect2, varscan2
- ARIH1 | c.1335G>A p.M445I | Missense Mutation (SNP) | VAF 93/763 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV65911901; called by muse, mutect2, varscan2
- ARL16 | c.145del p.R49Gfs*56 | Frame Shift Del (DEL) | VAF 27/219 reads (12%) | catalogued as COSV100230698; called by mutect2, pindel, varscan2
- ARMH3 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 97/724 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.145); catalogued as rs752261708; called by muse, mutect2, varscan2
- ASB16 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 70/527 reads (13%) | catalogued as rs372307713; called by muse, mutect2, varscan2
- ATP13A3 | c.598G>T p.V200L | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.325); catalogued as COSV99756811; called by muse, mutect2, varscan2
- BAHCC1 | c.2502dup p.H835Afs*239 | Frame Shift Ins (INS) | VAF 22/194 reads (11%) | catalogued as rs1555653772; called by mutect2, varscan2
- BCOR | c.3781del p.R1261Gfs*33 (on ENST00000378444 / NM_001123385.2; = p.R1227Gfs*33 on NM_017745.6) | Frame Shift Del (DEL) | VAF 53/312 reads (17%) | catalogued as COSV60707801; called by mutect2, pindel, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 62/447 reads (14%) | catalogued as rs768244116; called by mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 33/233 reads (14%) | catalogued as rs755506199; called by mutect2, varscan2
- BMP2 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 94/793 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs752683518, COSV66577006, COSV66578595; called by muse, mutect2, varscan2
- BMP2K | c.3076C>A p.R1026S | Missense Mutation (SNP) | VAF 66/419 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as rs780522133, COSV55011105; called by muse, mutect2, varscan2
- BOC | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 63/447 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs746840045; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 36/113 reads (32%) | catalogued as rs749043197; called by mutect2, varscan2
- BTNL8 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 131/690 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754512426, COSV51456653; called by muse, mutect2, varscan2
- C15orf39 | c.1120del p.Q374Rfs*3 | Frame Shift Del (DEL) | VAF 81/734 reads (11%) | catalogued as COSV100641264; called by mutect2, pindel, varscan2
- CACNA1C | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104404676, COSV59706212; called by muse, mutect2, varscan2
- CACNG6 | c.626del p.P209Rfs*21 (on ENST00000252729 / NM_145814.1; = p.P138Rfs*21 on NM_031897.2) | Frame Shift Del (DEL) | VAF 37/324 reads (11%) | catalogued as rs745648688, COSV53168096; called by mutect2, pindel, varscan2
- CAMTA1 | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 97/733 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as rs369691511; called by muse, mutect2, varscan2
- CCDC178 | c.2470G>A p.A824T (on ENST00000383096 / NM_001105528.3; = p.A786T on NM_198995.3) | Missense Mutation (SNP) | VAF 58/672 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs200388828, COSV100285008; called by muse, mutect2
- CCDC92 | c.801del p.I268Sfs*40 | Frame Shift Del (DEL) | VAF 37/368 reads (10%) | catalogued as rs773752200; called by mutect2, pindel, varscan2
- CCR7 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 74/489 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs141181444, COSV55850487; called by muse, mutect2, varscan2
- CD164L2 | c.383del p.P128Qfs*23 | Frame Shift Del (DEL) | VAF 39/334 reads (12%) | catalogued as rs755393856; called by mutect2, pindel, varscan2
- CD69 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 69/385 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs767001061, COSV57302241; called by muse, mutect2, varscan2
- CELSR1 | c.5544del p.T1849Rfs*8 | Frame Shift Del (DEL) | VAF 12/88 reads (14%) | catalogued as rs776824429; called by mutect2, pindel
- CEP112 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 35/328 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs776010708, COSV67142699; called by muse, mutect2, varscan2
- CEP350 | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 48/518 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs867400047; called by muse, mutect2
- CEP70 | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 59/555 reads (11%) | catalogued as rs751569983; called by muse, mutect2, varscan2
- CFAP46 | c.7654G>A p.G2552S | Missense Mutation (SNP) | VAF 46/403 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs372508852; called by muse, mutect2, varscan2
- CHD5 | c.3439C>T p.R1147C | Missense Mutation (SNP) | VAF 68/446 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52420803; called by muse, mutect2, varscan2
- CHGB | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 31/279 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs768860358; called by muse, mutect2, varscan2
- CHST1 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 61/551 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as COSV57322551; called by muse, mutect2, varscan2
- CHST13 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 58/340 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs755426222; called by muse, mutect2, varscan2
- CHST14 | c.1034G>C p.R345P | Missense Mutation (SNP) | VAF 46/323 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs991224324; called by muse, mutect2, varscan2
- CLDN6 | c.305C>A p.A102D | Missense Mutation (SNP) | VAF 163/1214 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV58509188; called by muse, mutect2, varscan2
- CLRN3 | c.262dup p.T88Nfs*84 | Frame Shift Ins (INS) | VAF 105/1024 reads (10%) | catalogued as rs748191748; called by mutect2, pindel, varscan2
- COL20A1 | c.3619G>A p.V1207M | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.194); catalogued as rs369702957; called by muse, mutect2, varscan2
- COL4A4 | c.999T>A p.D333E | Missense Mutation (SNP) | VAF 62/589 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV61633263; called by muse, mutect2, varscan2
- COL6A6 | c.5150G>A p.R1717H | Missense Mutation (SNP) | VAF 61/496 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.548); catalogued as rs756792501; called by muse, mutect2, varscan2
- COL6A6 | c.5722C>T p.R1908C | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs376975822; called by muse, mutect2
- CPSF7 | c.-53G>C | Splice Region (SNP) | VAF 49/322 reads (15%) | catalogued as COSV57100470; called by muse, mutect2, varscan2
- CSF1R | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 119/1042 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as rs1256984931, COSV53834937; called by muse, mutect2, varscan2
- CSMD1 | c.9637G>A p.A3213T (on ENST00000520002; = p.A3212T on NM_033225.6) | Missense Mutation (SNP) | VAF 47/373 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.98); catalogued as rs551310449, COSV59283291; called by muse, mutect2, varscan2
- CST9 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 52/367 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs569509447, COSV65402446; called by muse, mutect2, varscan2
- CTC1 | c.2249dup p.G751Rfs*40 | Frame Shift Ins (INS) | VAF 17/118 reads (14%) | catalogued as rs1254586169; called by mutect2, pindel, varscan2
- CTSC | c.343A>G p.T115A | Missense Mutation (SNP) | VAF 51/428 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs373283977; called by muse, mutect2, varscan2
- CYP11B2 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 129/1215 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs767044154; called by muse, mutect2, varscan2
- DCAF7 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 31/282 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60406735; called by muse, mutect2, varscan2
- DCHS1 | c.2884C>T p.P962S | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.19); catalogued as rs1024685143; called by muse, mutect2, varscan2
- DDX60 | c.3398del p.L1133Yfs*4 | Frame Shift Del (DEL) | VAF 26/205 reads (13%) | catalogued as rs778036194; called by mutect2, varscan2
- DGKQ | c.2644_2646del p.L882del | In Frame Del (DEL) | VAF 32/287 reads (11%) | catalogued as rs1157315754; called by pindel, varscan2
- DIAPH3 | c.3562G>A p.A1188T | Missense Mutation (SNP) | VAF 73/538 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1350483989; called by muse, mutect2, varscan2
- DLGAP3 | c.254del p.G85Vfs*215 | Frame Shift Del (DEL) | VAF 51/338 reads (15%) | catalogued as rs762874947; called by mutect2, varscan2
- DLL4 | c.1393A>G p.T465A | Missense Mutation (SNP) | VAF 91/697 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1223524485, COSV51070466; called by muse, mutect2, varscan2
- DMD | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 92/750 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1228664222, CM051908, COSV55886844, COSV99922377; called by muse, mutect2, varscan2
- DOCK10 | c.6472C>T p.R2158C | Missense Mutation (SNP) | VAF 86/643 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs774357482; called by muse, mutect2, varscan2
- DOK3 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 50/332 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.446); catalogued as rs775452189; called by muse, mutect2, varscan2
- EEF2 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs1238638025; called by muse, mutect2, varscan2
- EFS | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV53732941; called by muse, mutect2
- EIF3B | c.1085del p.G362Efs*28 | Frame Shift Del (DEL) | VAF 60/440 reads (14%) | catalogued as COSV62803535; called by mutect2, pindel, varscan2
- ELAPOR2 | c.1243_1245del p.P415del (on ENST00000450689 / NM_001142749.3; = p.P248del on NM_152748.4 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 22/198 reads (11%) | catalogued as rs780464668; called by pindel, varscan2
- ELAVL1 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 45/349 reads (13%) | catalogued as COSV60969153; called by muse, mutect2, varscan2
- ELOA2 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 76/756 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as rs1304952501; called by muse, mutect2, varscan2
- EP400 | c.8936C>T p.P2979L | Missense Mutation (SNP) | VAF 126/618 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs779505369; called by muse, mutect2, varscan2
- EPB41L3 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 68/619 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1392021881, COSV59453407; called by muse, mutect2, varscan2
- EPHX2 | c.4A>G p.T2A | Missense Mutation (SNP) | VAF 83/678 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1235585858; called by muse, mutect2, varscan2
- EPS15L1 | c.2665C>T p.R889W | Missense Mutation (SNP) | VAF 69/595 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs764162027; called by muse, mutect2, varscan2
- FAM149B1 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 74/1108 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs968366251, COSV99654940; called by muse, mutect2
- FAM160B1 | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 57/528 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs138422469, COSV65087282; called by muse, mutect2, varscan2
- FANCM | c.572C>A p.P191H | Missense Mutation (SNP) | VAF 54/402 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53534174; called by muse, mutect2, varscan2
- FAT3 | c.12677G>T p.G4226V | Missense Mutation (SNP) | VAF 97/781 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53105315; called by muse, mutect2, varscan2
- FECH | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 114/834 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1292029868; called by muse, mutect2, varscan2
- FGF4 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 149/883 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.277); catalogued as rs1194157859; called by muse, mutect2, varscan2
- FLG | c.4193G>A p.S1398N | Missense Mutation (SNP) | VAF 229/1670 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs1206679606; called by muse, mutect2, varscan2
- FMN2 | c.4065A>T p.Q1355H | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60458134; called by muse, mutect2
- FOSL2 | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 55/448 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs763475600, COSV53105197; called by muse, mutect2, varscan2
- FOXN1 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 46/376 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs2286520; called by muse, mutect2, varscan2
- FOXRED1 | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 62/609 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1416090738, COSV55005144; called by muse, mutect2, varscan2
- FRAS1 | c.11920C>T p.R3974W | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759074187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FUT6 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 96/715 reads (13%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.564); catalogued as rs766401715; called by muse, mutect2, varscan2
- GAA | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 59/432 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs777372252; called by muse, mutect2, varscan2
- GABRA4 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 69/655 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.202); catalogued as COSV51931816; called by muse, mutect2, varscan2
- GCC1 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 85/606 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1349179554; called by muse, mutect2, varscan2
- GET3 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs368392204; called by muse, mutect2, varscan2
- GGN | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 27/388 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); catalogued as rs763184194, COSV99287361; called by muse, mutect2
- GOLGA3 | c.4360C>T p.H1454Y | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760366618; called by muse, mutect2, varscan2
- GOLGA8Q | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 125/708 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1284996387; called by muse, mutect2, varscan2
- GRIK3 | c.1744G>A p.V582I | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.844); catalogued as rs371012951, COSV66136375, COSV66144296; called by muse, mutect2
- GRIN2B | c.4229C>T p.T1410M | Missense Mutation (SNP) | VAF 87/329 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as rs779830552; ClinVar: benign; called by muse, mutect2, varscan2
- GRM6 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 251/1095 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as rs1370098674; called by muse, mutect2, varscan2
- GTF3C1 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 64/584 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs756447771, COSV62241320; called by muse, mutect2, varscan2
- HDAC6 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 20/572 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs782123991; called by muse, mutect2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 23/180 reads (13%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPH2 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 64/479 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.42); catalogued as rs782446773; called by muse, mutect2, varscan2
- HOXA13 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as rs1463826659, COSV56084170; called by muse, mutect2
- HS3ST3A1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 32/447 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as rs1299495331; called by muse, mutect2
- HSF5 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1307796144, COSV60200821; called by muse, mutect2, varscan2
- IFFO1 | c.1089dup p.R364Afs*19 (on ENST00000396840 / NM_001330324.2; = p.R367Afs*19 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 54/490 reads (11%) | catalogued as rs750779916; called by mutect2, varscan2
- IGHV4-59 | c.341G>T p.C114F | Missense Mutation (SNP) | VAF 104/785 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1419427382; called by muse, mutect2, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 22/124 reads (18%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs761880048; called by mutect2, varscan2
- IRS4 | c.1772del p.G591Afs*20 | Frame Shift Del (DEL) | VAF 79/638 reads (12%) | catalogued as rs780982673; called by mutect2, varscan2
- ITGB1 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 74/513 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1378099428; called by muse, mutect2, varscan2
- JMJD8 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 64/449 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.281); catalogued as rs200168703, COSV50199059; called by muse, mutect2, varscan2
- KCNA5 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 80/1111 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.8); catalogued as rs765380398, COSV52904032, COSV99363787; called by muse, mutect2
- KCNB2 | c.2719C>T p.R907C | Missense Mutation (SNP) | VAF 92/276 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.871); catalogued as rs567445185; called by muse, mutect2, varscan2
- KCNH4 | c.588C>T p.N196= | Splice Region (SNP) | VAF 29/291 reads (10%) | catalogued as rs369640270; called by muse, mutect2, varscan2
- KCNN3 | c.2210C>T p.P737L (on ENST00000618040 / NM_001204087.1; = p.P722L on NM_002249.6) | Missense Mutation (SNP) | VAF 40/259 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.228); catalogued as rs774384644, COSV55228679; called by muse, mutect2, varscan2
- KDM6B | c.1537del p.R513Afs*69 | Frame Shift Del (DEL) | VAF 47/364 reads (13%) | catalogued as rs747555402; called by mutect2, pindel, varscan2
- KHDC3L | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 120/906 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as rs769425065, COSV64863247; called by muse, mutect2, varscan2
- KIAA1522 | c.172dup p.H58Pfs*46 (on ENST00000373480 / NM_001198972.2; = p.H117Pfs*46 on NM_020888.3) | Frame Shift Ins (INS) | VAF 56/464 reads (12%) | catalogued as rs767600627; called by mutect2, varscan2
- KIF15 | c.3709C>T p.P1237S | Missense Mutation (SNP) | VAF 19/233 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs762847739; called by muse, mutect2
- KIF17 | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 104/750 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370700388; called by muse, mutect2, varscan2
- KIF22 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 135/963 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748823568; called by muse, mutect2, varscan2
- KLF15 | c.933G>T p.K311N | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750849615; called by muse, mutect2, varscan2
- KLK11 | c.833C>T p.T278M (on ENST00000594768 / NM_144947.3; = p.T246M on NM_006853.3) | Missense Mutation (SNP) | VAF 114/1006 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs778575456, COSV59398795; called by muse, mutect2, varscan2
- KMT2D | c.14473C>T p.R4825W | Missense Mutation (SNP) | VAF 137/592 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs117904191; called by muse, mutect2, varscan2
- KPNA4 | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62075014; called by muse, mutect2
- LAMC1 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs752108997; called by muse, mutect2
- LATS1 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV53600175; called by muse, mutect2, varscan2
- LCE1D | c.62C>T p.T21I | Missense Mutation (SNP) | VAF 95/355 reads (27%) | PolyPhen benign (0.019); catalogued as rs376151801; called by muse, mutect2, varscan2
- LOXHD1 | c.5467C>T p.R1823W (on ENST00000642948; = p.R1761W on NM_144612.7) | Missense Mutation (SNP) | VAF 50/569 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759919888, COSV56061253; called by muse, mutect2
- LRP6 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 69/652 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs759106535, COSV53786736; called by muse, mutect2, varscan2
- LRRC4B | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 56/441 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65349270; called by muse, mutect2, varscan2
- LYST | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 39/315 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs1361872807; called by muse, mutect2, varscan2
- MAPK4 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 26/373 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs186595195, COSV68541012; called by muse, mutect2
- MAPK8IP3 | c.3906_3908del p.D1302del | In Frame Del (DEL) | VAF 75/625 reads (12%) | catalogued as rs772305360; called by pindel, varscan2
- MAST4 | c.7525G>A p.G2509R (on ENST00000403625 / NM_001164664.2; = p.G2320R on NM_015183.3) | Missense Mutation (SNP) | VAF 60/440 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs760215018; called by muse, mutect2, varscan2
- MCM2 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 73/673 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs35343063; called by muse, mutect2, varscan2
- MFN1 | c.1600C>T p.R534* | Nonsense Mutation (SNP) | VAF 36/379 reads (9%) | catalogued as rs1272208650; called by muse, mutect2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 41/262 reads (16%) | catalogued as rs750307488; called by mutect2, varscan2
- MUC12 | c.2056C>T p.P686S (on ENST00000379442; = p.P543S on NM_001164462.1) | Missense Mutation (SNP) | VAF 107/1277 reads (8%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.65); catalogued as rs765249028; called by muse, mutect2
- MUC5B | c.4708G>A p.V1570I | Missense Mutation (SNP) | VAF 54/388 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.743); catalogued as rs200722081; called by muse, mutect2, varscan2
- MUC5B | c.11578G>A p.A3860T | Missense Mutation (SNP) | VAF 155/1229 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1247568195; called by muse, mutect2, varscan2
- MYH8 | c.868dup p.Y290Lfs*7 | Frame Shift Ins (INS) | VAF 69/550 reads (13%) | catalogued as rs1319380590; called by mutect2, pindel, varscan2
- MYO9B | c.3803C>T p.A1268V | Missense Mutation (SNP) | VAF 166/1330 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1349805194; called by muse, mutect2, varscan2
- NBPF4 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 48/938 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1431116384, COSV70321231; called by muse, mutect2
- NBPF6 | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 92/1850 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs937522714, COSV99640497; called by muse, mutect2
- NEB | c.6887C>T p.A2296V | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1411704072; called by muse, mutect2, varscan2
- NFKBIZ | c.2008C>T p.R670C | Missense Mutation (SNP) | VAF 71/710 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs777315234; called by muse, mutect2
- NMRK2 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 93/713 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs369195071; called by muse, mutect2, varscan2
- NMT1 | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 31/364 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs773052955, COSV51959439; called by muse, mutect2
- NOTCH2 | c.6892C>T p.R2298W | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs1270274564, COSV56685860; called by muse, mutect2, varscan2
- NPHS1 | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 80/614 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756579664; called by muse, mutect2, varscan2
- NPR1 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 114/1018 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as rs779546718, COSV64118127; called by muse, mutect2, varscan2
- NPR1 | c.1818del p.N607Ifs*62 | Frame Shift Del (DEL) | VAF 39/338 reads (12%) | catalogued as rs772189906; called by mutect2, pindel, varscan2
- NR2F6 | c.1208G>A p.G403D | Missense Mutation (SNP) | VAF 93/566 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.69); catalogued as rs770595526; called by muse, mutect2, varscan2
- NSD2 | c.2792C>T p.T931M | Missense Mutation (SNP) | VAF 58/468 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs767627490; called by muse, mutect2, varscan2
- NT5E | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV57628838; called by muse, mutect2
- NUTF2 | c.99+1G>A p.X33_splice | Splice Site (SNP) | VAF 14/128 reads (11%) | catalogued as COSV54645854; called by muse, mutect2
- OBSCN | c.14027G>A p.R4676Q | Missense Mutation (SNP) | VAF 112/1039 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs748800682; called by muse, mutect2, varscan2
- OPA1 | c.2228C>T p.P743L (on ENST00000361510 / NM_130837.3; = p.P688L on NM_015560.3) | Missense Mutation (SNP) | VAF 28/355 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs746579947, COSV62479825; called by muse, mutect2
- OPLAH | c.2704C>T p.R902W | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.606); catalogued as rs782146729; called by muse, mutect2
- OR52L1 | c.892T>C p.Y298H | Missense Mutation (SNP) | VAF 85/640 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188774432; called by muse, mutect2, varscan2
- OR5D16 | c.676A>G p.T226A | Missense Mutation (SNP) | VAF 64/620 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as rs981647723; called by muse, mutect2
- ORMDL2 | c.392T>C p.L131S | Missense Mutation (SNP) | VAF 131/622 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs201630136; called by muse, mutect2, varscan2
- PACS2 | c.290_292del p.S97del | In Frame Del (DEL) | VAF 52/454 reads (11%) | catalogued as rs782429503; called by mutect2, pindel, varscan2
- PAPPA2 | c.2635A>G p.S879G | Missense Mutation (SNP) | VAF 50/481 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs1430605269; called by muse, mutect2, varscan2
- PAXIP1 | c.638G>A p.S213N | Missense Mutation (SNP) | VAF 53/463 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.931); catalogued as rs745791091; called by muse, mutect2, varscan2
- PCDHGA1 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 335/1059 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.537); catalogued as rs577475018, COSV65299631; called by muse, mutect2, varscan2
- PCDHGA5 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 132/511 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); catalogued as rs746525916; called by muse, mutect2, varscan2
- PCK1 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 35/302 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.054); catalogued as rs755135303; called by muse, mutect2, varscan2
- PCLO | c.248+1G>A p.X83_splice | Splice Site (SNP) | VAF 49/397 reads (12%) | catalogued as COSV61625940; called by muse, mutect2, varscan2
- PDE4D | c.560G>A p.R187Q (on ENST00000340635 / NM_001104631.2; = p.R51Q on NM_006203.4) | Missense Mutation (SNP) | VAF 203/992 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as rs765474542; called by muse, mutect2, varscan2
- PEX2 | c.535A>G p.K179E | Missense Mutation (SNP) | VAF 50/533 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as rs1384124243; called by muse, mutect2
- PHIP | c.3768_3770del p.L1257del | In Frame Del (DEL) | VAF 20/176 reads (11%) | catalogued as rs964550052; called by pindel, varscan2
- PIWIL1 | c.1866C>T p.P622= | Splice Region (SNP) | VAF 76/606 reads (13%) | catalogued as rs562377597, COSV55348336; called by muse, mutect2, varscan2
- PKD1 | c.1006G>A p.V336M | Missense Mutation (SNP) | VAF 111/1094 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.88); catalogued as rs749740622; called by muse, mutect2, varscan2
- PKN1 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as rs750915489; called by muse, mutect2, varscan2
- PLAGL2 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as rs763383983; called by muse, mutect2, varscan2
- PLCE1 | c.6902G>A p.R2301Q | Missense Mutation (SNP) | VAF 82/675 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs776445270, COSV99595074; called by muse, mutect2, varscan2
- PLEKHA4 | c.379G>T p.G127C | Missense Mutation (SNP) | VAF 75/578 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99612295; called by muse, mutect2, varscan2
- PML | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 163/1213 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs77069486; called by muse, mutect2, varscan2
- PPIP5K2 | c.3292G>A p.A1098T | Missense Mutation (SNP) | VAF 97/422 reads (23%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs984944764; called by muse, mutect2, varscan2
- PPL | c.2967del p.Q990Rfs*31 | Frame Shift Del (DEL) | VAF 112/878 reads (13%) | catalogued as rs762995701; called by mutect2, pindel, varscan2
- PPP1R12A | c.1619del p.N540Ifs*23 | Frame Shift Del (DEL) | VAF 47/296 reads (16%) | catalogued as rs776166170; called by mutect2, varscan2
- PPP1R16B | c.1436C>T p.T479M | Missense Mutation (SNP) | VAF 117/944 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201345539, COSV55381861; called by muse, mutect2, varscan2
- PPP1R3C | c.259T>C p.F87L | Missense Mutation (SNP) | VAF 38/267 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53289745; called by muse, mutect2, varscan2
- PRC1 | c.1368dup p.Q457Tfs*16 | Frame Shift Ins (INS) | VAF 57/532 reads (11%) | catalogued as rs1231355293; called by mutect2, pindel
- PRDM15 | c.647del p.P216Rfs*22 | Frame Shift Del (DEL) | VAF 85/619 reads (14%) | catalogued as COSV54156899; called by mutect2, pindel, varscan2
- PRKAA1 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1433191043, COSV57185721; called by muse, mutect2, varscan2
- PRKCA | c.1406T>C p.V469A | Missense Mutation (SNP) | VAF 32/268 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52579554; called by muse, mutect2, varscan2
- PRKCQ | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 28/375 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1274566995, COSV54106426; called by muse, mutect2
- PRR12 | c.2725G>A p.E909K (on ENST00000615927; = p.E1730K on NM_020719.3) | Missense Mutation (SNP) | VAF 81/596 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs774390630, COSV69817178; called by muse, mutect2, varscan2
- PTPRK | c.3112C>T p.R1038C (on ENST00000368215 / NM_001291984.2; = p.R1039C on NM_002844.4) | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766336327; called by muse, varscan2
- PTPRM | c.2805C>T p.Y935= | Splice Region (SNP) | VAF 35/281 reads (12%) | catalogued as rs1004054600, COSV100154107; called by muse, mutect2, varscan2
- PXN | c.1432G>T p.G478C (on ENST00000228307 / NM_001080855.3; = p.G444C on NM_002859.4) | Missense Mutation (SNP) | VAF 112/1129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57218204; called by muse, mutect2, varscan2
- RALGPS1 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 65/610 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as rs374751575; called by muse, mutect2, varscan2
- RALYL | c.411T>C p.N137= | Splice Region (SNP) | VAF 10/184 reads (5%) | catalogued as rs1012978435; called by muse, mutect2
- RASSF5 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 52/450 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553407065; called by muse, mutect2
- RECQL5 | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 54/508 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754357449, COSV58638299; called by muse, mutect2, varscan2
- RERG | c.395_397del p.E132del | In Frame Del (DEL) | VAF 46/255 reads (18%) | catalogued as rs758989434; called by pindel, varscan2
- ROMO1 | c.175del p.T59Pfs*2 | Frame Shift Del (DEL) | VAF 90/919 reads (10%) | catalogued as COSV53616533; called by mutect2, pindel, varscan2
- RPL4 | c.282C>T p.N94= | Splice Region (SNP) | VAF 38/235 reads (16%) | catalogued as rs544008700, COSV100328767; called by muse, mutect2, varscan2
- RPN1 | c.1363_1365del p.I455del | In Frame Del (DEL) | VAF 80/668 reads (12%) | catalogued as rs1186229975; called by pindel, varscan2
- RRBP1 | c.184_186del p.K62del | In Frame Del (DEL) | VAF 72/653 reads (11%) | catalogued as rs777987396; called by pindel, varscan2
- RYR1 | c.5461G>A p.D1821N | Missense Mutation (SNP) | VAF 39/317 reads (12%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.588); catalogued as rs139709595, COSV62089374; called by muse, mutect2, varscan2
- RYR2 | c.13823G>A p.R4608Q | Missense Mutation (SNP) | VAF 45/417 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs1553328170, CM148846, COSV63697882; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.4944G>T p.K1648N | Missense Mutation (SNP) | VAF 60/528 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); catalogued as COSV101213397; called by muse, mutect2, varscan2
- RYR3 | c.10046G>A p.R3349Q (on ENST00000389232; = p.R3350Q on NM_001036.6) | Missense Mutation (SNP) | VAF 52/382 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); catalogued as rs370501059; called by muse, mutect2, varscan2
- SAMD11 | c.1237dup p.Q413Pfs*42 | Frame Shift Ins (INS) | VAF 48/346 reads (14%) | catalogued as rs1223597129; called by mutect2, varscan2
- SART1 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 59/512 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as rs754233385, COSV56710749; called by muse, mutect2, varscan2
- SCN1B | c.59dup p.C21Lfs*32 | Frame Shift Ins (INS) | VAF 90/785 reads (11%) | catalogued as rs1568348569; called by mutect2, pindel, varscan2
- SCN9A | c.5542C>T p.R1848C (on ENST00000303354; = p.R1837C on NM_002977.3) | Missense Mutation (SNP) | VAF 75/637 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1381335907, COSV57622475; called by muse, mutect2, varscan2
- SCRN2 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 49/392 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV51634736, COSV99274393; called by muse, mutect2, varscan2
- SDK2 | c.3316C>T p.R1106C | Missense Mutation (SNP) | VAF 86/715 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs766963724, COSV101166609; called by muse, mutect2, varscan2
- SECISBP2L | c.2924C>A p.S975Y (on ENST00000559471 / NM_001193489.2; = p.S930Y on NM_014701.4) | Missense Mutation (SNP) | VAF 102/659 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55933903; called by muse, mutect2, varscan2
- SEMA3E | c.1997G>A p.R666H | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as rs779454555, COSV100319243; called by muse, mutect2, varscan2
- SETMAR | c.589A>G p.R197G | Missense Mutation (SNP) | VAF 41/381 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs776571663; called by muse, mutect2, varscan2
- SH3BP1 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs768016525; called by muse, mutect2
- SIAE | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 97/820 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs766546682; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 66/252 reads (26%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC37A3 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 72/582 reads (12%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.98); catalogued as rs773189820; called by muse, mutect2, varscan2
- SLC7A4 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 63/480 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as rs759478605, COSV60384776; called by muse, mutect2, varscan2
- SLC8A2 | c.658del p.S220Pfs*12 | Frame Shift Del (DEL) | VAF 33/240 reads (14%) | catalogued as rs748349403; called by mutect2, pindel, varscan2
- SLC9A1 | c.895_897del p.F299del | In Frame Del (DEL) | VAF 123/1014 reads (12%) | catalogued as rs760438825; called by pindel, varscan2
- SLC9A3 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 101/438 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1305643927, COSV53801601; called by muse, mutect2, varscan2
- SMCO2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 94/495 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.179); catalogued as rs535258341; called by muse, mutect2, varscan2
- SOGA1 | c.3559C>T p.R1187W | Missense Mutation (SNP) | VAF 95/592 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs200024274, COSV52933275; called by muse, mutect2, varscan2
- SORBS3 | c.1586C>T p.T529M | Missense Mutation (SNP) | VAF 50/388 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs369519218; called by muse, mutect2, varscan2
- SP110 | c.1691del p.P564Lfs*16 | Frame Shift Del (DEL) | VAF 56/531 reads (11%) | catalogued as rs1245290762; called by mutect2, pindel, varscan2
- SPAG7 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 122/1222 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs1050465869; called by muse, mutect2
- SUPT5H | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.18); catalogued as rs757236653, COSV63240896; called by muse, mutect2
- SUSD2 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as rs748381886; called by muse, mutect2, varscan2
- SYNE3 | c.2376C>T p.R792= | Splice Region (SNP) | VAF 19/182 reads (10%) | catalogued as rs1335352974, COSV62081587; called by muse, mutect2, varscan2
- TAX1BP1 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 36/462 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs112084378; called by muse, mutect2
- TDRD12 | c.3415C>T p.Q1139* (on ENST00000444215; = p.Q1144* on NM_001366102.1) | Nonsense Mutation (SNP) | VAF 62/525 reads (12%) | catalogued as rs1568499243; called by muse, mutect2, varscan2
- TECPR1 | c.2797G>A p.A933T | Missense Mutation (SNP) | VAF 83/626 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1368685802, COSV65783352; called by mutect2, varscan2
- TELO2 | c.2299C>T p.R767C | Missense Mutation (SNP) | VAF 29/347 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748283125, COSV99248637; called by muse, mutect2
- TET3 | c.3973C>T p.H1325Y | Missense Mutation (SNP) | VAF 88/724 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV101328031; called by muse, mutect2, varscan2
- TJP1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 32/226 reads (14%) | catalogued as rs1439465484; called by muse, mutect2, varscan2
- TJP3 | c.1990G>A p.V664M | Missense Mutation (SNP) | VAF 58/581 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372340881; called by muse, mutect2, varscan2
- TLR9 | c.3007C>T p.R1003C | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs200911364; called by muse, varscan2
- TMCO4 | c.1114dup p.V372Gfs*221 | Frame Shift Ins (INS) | VAF 50/426 reads (12%) | catalogued as rs1448460164; called by mutect2, varscan2
- TMEM132B | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 56/503 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as COSV54746183; called by muse, mutect2, varscan2
- TMEM17 | c.84G>T p.E28D | Missense Mutation (SNP) | VAF 102/809 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV59023469; called by muse, mutect2, varscan2
- TMEM18 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 31/517 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774495261; called by muse, mutect2
- TPCN2 | c.2014A>G p.I672V | Missense Mutation (SNP) | VAF 61/442 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as rs1355049608; called by muse, mutect2, varscan2
- TPR | c.3287T>C p.L1096P | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66600151; called by muse, mutect2, varscan2
- TRA2B | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 32/299 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV52025194; called by muse, mutect2, varscan2
- TRIM44 | c.337A>T p.T113S | Missense Mutation (SNP) | VAF 143/975 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs1196630044; called by muse, mutect2, varscan2
- TRIM58 | c.592C>A p.Q198K | Missense Mutation (SNP) | VAF 95/1008 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV63570523; called by muse, mutect2
- TRIOBP | c.2107C>T p.R703W | Missense Mutation (SNP) | VAF 177/1380 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.972); catalogued as rs1440271065; called by muse, varscan2
- TTC24 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 126/922 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); catalogued as rs527644191; called by muse, mutect2, varscan2
- TTN | c.58406C>T p.A19469V (on ENST00000591111; = p.A12045V on NM_003319.4) | Missense Mutation (SNP) | VAF 22/266 reads (8%) | PolyPhen benign (0.035); catalogued as rs370687831; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2
- UROC1 | c.920del p.K307Rfs*77 | Frame Shift Del (DEL) | VAF 94/771 reads (12%) | catalogued as rs754361807; called by mutect2, varscan2
- USP35 | c.1059del p.M354Wfs*119 | Frame Shift Del (DEL) | VAF 26/188 reads (14%) | catalogued as rs761345427; called by mutect2, pindel
- VPS13A | c.6283T>C p.S2095P | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as CD022727; called by muse, mutect2, varscan2
- VPS13C | c.4836_4839del p.C1613Ifs*20 (on ENST00000644861 / NM_020821.3; = p.C1570Ifs*20 on NM_017684.5) | Frame Shift Del (DEL) | VAF 15/164 reads (9%) | catalogued as rs1479319076; called by mutect2, pindel
- VWA3B | c.3763G>A p.G1255R | Missense Mutation (SNP) | VAF 97/732 reads (13%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs756947295; called by muse, mutect2, varscan2
- WARS2 | c.887G>A p.G296D | Missense Mutation (SNP) | VAF 76/672 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV99346747; called by muse, mutect2, varscan2
- YIPF7 | c.469dup p.C157Lfs*87 | Frame Shift Ins (INS) | VAF 38/344 reads (11%) | catalogued as rs775056622; called by mutect2, pindel, varscan2
- ZACN | c.589_592del p.V198Rfs*5 | Frame Shift Del (DEL) | VAF 53/537 reads (10%) | catalogued as rs766215353; called by mutect2, pindel
- ZFC3H1 | c.5548T>G p.C1850G | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV66434267; called by muse, mutect2, varscan2
- ZNF219 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 33/353 reads (9%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.547); catalogued as rs1161853144, COSV53884912; called by muse, mutect2
- ZNF302 | c.509A>G p.E170G (on ENST00000627982; = p.E91G on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs1386409233; called by muse, mutect2, varscan2
- ZNF395 | c.700del p.H234Tfs*43 | Frame Shift Del (DEL) | VAF 22/159 reads (14%) | catalogued as rs768191349; called by mutect2, pindel
- ZNF423 | c.3328G>A p.G1110R (on ENST00000563137 / NM_001379286.1; = p.G1102R on NM_015069.4) | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs552943301; called by muse, mutect2, varscan2
- ZNF488 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 83/538 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs144604527; called by muse, mutect2, varscan2
- ZNF579 | c.1063del p.A355Rfs*50 | Frame Shift Del (DEL) | VAF 27/161 reads (17%) | catalogued as COSV57638435; called by mutect2, pindel, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 56/545 reads (10%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF800 | c.1091G>A p.C364Y | Missense Mutation (SNP) | VAF 14/253 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56178876; called by muse, mutect2
- ZPLD1 | c.5A>G p.E2G (on ENST00000466937 / NM_001329788.1; = p.E18G on NM_175056.2) | Missense Mutation (SNP) | VAF 20/363 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.123); catalogued as COSV60353004; called by muse, mutect2
- ZSCAN22 | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 38/534 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.161); catalogued as rs149655686; called by muse, mutect2
- A2ML1 | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 38/335 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2
- A4GALT | c.201del p.T68Pfs*46 | Frame Shift Del (DEL) | VAF 76/692 reads (11%) | called by mutect2, pindel
- ABCA6 | c.2687C>T p.P896L | Missense Mutation (SNP) | VAF 51/482 reads (11%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- ABCA6 | c.2110T>C p.W704R | Missense Mutation (SNP) | VAF 26/417 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ABCB11 | c.2334G>T p.Q778H | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ABCB9 | c.806T>C p.L269P | Missense Mutation (SNP) | VAF 73/661 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACOXL | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 64/505 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADCY8 | c.2294A>G p.K765R | Missense Mutation (SNP) | VAF 69/1090 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2
- ADD1 | c.1206_1207del p.K403Vfs*2 | Frame Shift Del (DEL) | VAF 44/428 reads (10%) | called by pindel, varscan2
- ADORA2B | c.746C>A p.P249H | Missense Mutation (SNP) | VAF 93/752 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADRA2C | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 74/467 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AFF3 | c.1160C>T p.T387M | Missense Mutation (SNP) | VAF 79/658 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- AFTPH | c.1241del p.N414Mfs*9 | Frame Shift Del (DEL) | VAF 67/510 reads (13%) | called by mutect2, pindel, varscan2
- AHCTF1 | c.1987_1989del p.L663del (on ENST00000366508; = p.L637del on NM_015446.5) | In Frame Del (DEL) | VAF 50/357 reads (14%) | called by pindel, varscan2
- AHNAK | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 52/336 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AHSA1 | c.237_239del p.F80del | In Frame Del (DEL) | VAF 78/751 reads (10%) | called by pindel, varscan2
- ALK | c.4379del p.E1460Gfs*17 | Frame Shift Del (DEL) | VAF 61/228 reads (27%) | called by mutect2, pindel*, varscan2*
- ALPK1 | c.1504A>G p.T502A | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- ALPK3 | c.2927G>T p.S976I | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- AMIGO2 | c.1393dup p.R465Kfs*30 | Frame Shift Ins (INS) | VAF 109/627 reads (17%) | called by mutect2, pindel, varscan2
- AP2A1 | c.2551del p.Q851Rfs*5 | Frame Shift Del (DEL) | VAF 44/357 reads (12%) | called by mutect2, pindel, varscan2
- AP3B1 | c.46dup p.E16Gfs*23 | Frame Shift Ins (INS) | VAF 198/1046 reads (19%) | called by mutect2, pindel, varscan2
- AP5B1 | c.1014G>C p.L338F | Missense Mutation (SNP) | VAF 52/406 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AREL1 | c.95T>C p.F32S | Missense Mutation (SNP) | VAF 135/1181 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ARMC5 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ASMTL | c.1598A>G p.D533G | Missense Mutation (SNP) | VAF 83/655 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- ATG2B | c.1794del p.F598Lfs*32 | Frame Shift Del (DEL) | VAF 28/310 reads (9%) | called by mutect2, pindel
- ATP11B | c.1037del p.L346Wfs*14 | Frame Shift Del (DEL) | VAF 29/192 reads (15%) | called by mutect2, pindel, varscan2
- B4GALNT1 | c.677G>T p.S226I | Missense Mutation (SNP) | VAF 197/1512 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- BCAN | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2
- BNC2 | c.1817del p.P606Rfs*7 | Frame Shift Del (DEL) | VAF 50/460 reads (11%) | called by mutect2, pindel, varscan2
- BOD1L1 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BRF2 | c.286T>A p.Y96N | Missense Mutation (SNP) | VAF 83/791 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- BRIP1 | c.2446T>C p.W816R | Missense Mutation (SNP) | VAF 67/520 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BSN | c.8702dup p.P2902Sfs*53 | Frame Shift Ins (INS) | VAF 20/99 reads (20%) | called by mutect2, pindel, varscan2
- C5orf63 | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 112/428 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- C8B | c.424G>T p.G142W | Missense Mutation (SNP) | VAF 130/1090 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNG3 | c.514dup p.S172Kfs*31 | Frame Shift Ins (INS) | VAF 34/290 reads (12%) | called by mutect2, varscan2
- CALR3 | c.193G>T p.G65C | Missense Mutation (SNP) | VAF 97/765 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPN1 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 64/665 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPRIN2 | c.1987+2T>C p.X663_splice | Splice Site (SNP) | VAF 51/485 reads (11%) | called by muse, mutect2, varscan2
- CCDC93 | c.1175T>C p.M392T | Missense Mutation (SNP) | VAF 40/373 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD248 | c.2229del p.R744Gfs*61 | Frame Shift Del (DEL) | VAF 56/438 reads (13%) | called by mutect2, pindel
- CD36 | c.1348A>G p.S450G | Missense Mutation (SNP) | VAF 81/649 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDAN1 | c.2476A>T p.K826* | Nonsense Mutation (SNP) | VAF 72/840 reads (9%) | called by muse, mutect2
- CDH22 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH26 | c.47T>C p.V16A | Missense Mutation (SNP) | VAF 68/546 reads (12%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH7 | c.674A>G p.Q225R | Missense Mutation (SNP) | VAF 47/358 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- CEMIP | c.2570C>A p.P857H | Missense Mutation (SNP) | VAF 44/1374 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); called by muse, mutect2
- CEP128 | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 62/556 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CEP295NL | c.399G>T p.Q133H | Missense Mutation (SNP) | VAF 85/562 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CIT | c.2779-5T>C | Splice Region (SNP) | VAF 48/221 reads (22%) | called by muse, mutect2, varscan2
- CLCN6 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 57/534 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CLDND1 | c.232T>C p.W78R | Missense Mutation (SNP) | VAF 40/306 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLEC16A | c.3083C>T p.S1028F | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CLEC18B | c.878-1G>T p.X293_splice | Splice Site (SNP) | VAF 56/1440 reads (4%) | called by muse, mutect2
- CMYA5 | c.7268A>G p.D2423G | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- COPS5 | c.871A>G p.T291A | Missense Mutation (SNP) | VAF 51/738 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- CRP | c.67T>A p.S23T | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2
- CSTF2 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 155/1156 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CTNNA3 | c.1104del p.K369Rfs*14 | Frame Shift Del (DEL) | VAF 27/274 reads (10%) | called by mutect2, pindel, varscan2
- DBNDD2 | c.235T>C p.C79R | Missense Mutation (SNP) | VAF 140/1059 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCAF10 | c.1337_1339del p.E446del | In Frame Del (DEL) | VAF 15/113 reads (13%) | called by pindel, varscan2
- DCAF12L1 | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 70/412 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- DCDC1 | c.1358A>G p.N453S | Missense Mutation (SNP) | VAF 63/429 reads (15%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- DDX24 | c.465_468del p.K156Ifs*54 | Frame Shift Del (DEL) | VAF 66/733 reads (9%) | called by mutect2, pindel
- DERL2 | c.629A>T p.D210V | Missense Mutation (SNP) | VAF 36/386 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- DNAAF5 | c.1817T>C p.V606A | Missense Mutation (SNP) | VAF 50/373 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- DNAH10 | c.12683G>A p.G4228D (on ENST00000409039; = p.G4167D on NM_207437.3) | Missense Mutation (SNP) | VAF 74/888 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); called by muse, mutect2
- DNAH14 | c.9745C>T p.Q3249* (on ENST00000445597; = p.Q4257* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 20/159 reads (13%) | called by muse, mutect2, varscan2
- DNAH3 | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 84/654 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- DRAM1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 77/356 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- DSG4 | c.1990G>T p.G664* | Nonsense Mutation (SNP) | VAF 194/1491 reads (13%) | called by muse, mutect2, varscan2
- DUOXA1 | c.817A>G p.R273G | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.569); called by muse, mutect2
- DUOXA2 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 53/554 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- DYNC1H1 | c.9988del p.E3330Kfs*34 | Frame Shift Del (DEL) | VAF 86/772 reads (11%) | called by mutect2, pindel, varscan2
- EHBP1L1 | c.3389T>C p.V1130A | Missense Mutation (SNP) | VAF 51/678 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- EIPR1 | c.11A>G p.D4G | Missense Mutation (SNP) | VAF 43/464 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- ELMO1 | c.827T>A p.L276* | Nonsense Mutation (SNP) | VAF 52/531 reads (10%) | called by muse, mutect2
- ELMO2 | c.1423C>T p.Q475* | Nonsense Mutation (SNP) | VAF 45/336 reads (13%) | called by muse, mutect2
- ELP5 | c.479_480del p.K160Sfs*9 | Frame Shift Del (DEL) | VAF 74/665 reads (11%) | called by mutect2, pindel, varscan2
- EML2 | c.1840T>C p.Y614H | Missense Mutation (SNP) | VAF 50/535 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- ENGASE | c.416+1G>A p.X139_splice | Splice Site (SNP) | VAF 91/569 reads (16%) | called by muse, mutect2, varscan2
- ENO4 | c.1167A>T p.E389D (on ENST00000622726; = p.E386D on NM_001242699.2) | Missense Mutation (SNP) | VAF 61/401 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ENTPD1 | c.1074+2T>C p.X358_splice | Splice Site (SNP) | VAF 72/699 reads (10%) | called by muse, mutect2, varscan2
- EP300 | c.4408del p.M1470Cfs*26 | Frame Shift Del (DEL) | VAF 86/697 reads (12%) | called by pindel, varscan2
- EPB41L4A | c.739A>T p.I247F | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPHA2 | c.1379del p.P460Rfs*33 | Frame Shift Del (DEL) | VAF 75/675 reads (11%) | called by mutect2, pindel, varscan2
- EPHA4 | c.2377C>T p.P793S | Missense Mutation (SNP) | VAF 64/332 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERCC6L2 | c.3043A>G p.N1015D | Missense Mutation (SNP) | VAF 26/337 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.02); called by muse, mutect2
- EVC | c.1280dup p.A428Gfs*49 | Frame Shift Ins (INS) | VAF 103/812 reads (13%) | called by mutect2, pindel, varscan2
- F13A1 | c.1514del p.K505Sfs*9 | Frame Shift Del (DEL) | VAF 76/664 reads (11%) | called by mutect2, pindel, varscan2
- FAAP24 | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 46/567 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM118A | c.512A>G p.D171G | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, varscan2
- FAM155B | c.929T>C p.V310A | Missense Mutation (SNP) | VAF 52/400 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- FAM241B | c.145dup p.R49Pfs*18 | Frame Shift Ins (INS) | VAF 74/629 reads (12%) | called by mutect2, pindel, varscan2
- FBLN1 | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 120/1101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FBXO44 | c.232C>T p.H78Y | Missense Mutation (SNP) | VAF 80/412 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- FGFR1OP2 | c.652C>A p.L218I | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FHAD1 | c.1982_1984del p.G661del | In Frame Del (DEL) | VAF 44/429 reads (10%) | called by mutect2, pindel, varscan2
- FKRP | c.948dup p.C317Lfs*73 | Frame Shift Ins (INS) | VAF 58/490 reads (12%) | called by mutect2, pindel, varscan2
- FOXD2 | c.1394G>A p.G465D | Missense Mutation (SNP) | VAF 124/940 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FOXD3 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 125/962 reads (13%) | called by muse, mutect2, varscan2
- FSIP2 | c.630_632del p.M210del | In Frame Del (DEL) | VAF 24/165 reads (15%) | called by mutect2, pindel, varscan2
- FSIP2 | c.12501del p.K4167Nfs*3 | Frame Shift Del (DEL) | VAF 12/87 reads (14%) | called by mutect2, pindel, varscan2
- FUBP3 | c.1184del p.P395Lfs*27 | Frame Shift Del (DEL) | VAF 19/173 reads (11%) | called by mutect2, pindel, varscan2
- FZD3 | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 59/483 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- GALC | c.1147A>T p.I383F | Missense Mutation (SNP) | VAF 87/667 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- GALNT12 | c.1495A>G p.N499D | Missense Mutation (SNP) | VAF 164/1232 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GAS7 | c.29A>G p.Y10C | Missense Mutation (SNP) | VAF 73/613 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GASK1B | c.767C>A p.A256D | Missense Mutation (SNP) | VAF 26/950 reads (3%) | SIFT tolerated (0.65); PolyPhen benign (0.049); called by muse, mutect2
- GDF6 | c.349T>C p.F117L | Missense Mutation (SNP) | VAF 301/926 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GFER | c.62del p.G21Afs*6 | Frame Shift Del (DEL) | VAF 48/427 reads (11%) | called by mutect2, pindel, varscan2
- GGA3 | c.8A>G p.E3G | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- GLRA3 | c.1346T>C p.V449A | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GLYR1 | c.678_679del p.K227Afs*16 | Frame Shift Del (DEL) | VAF 55/444 reads (12%) | called by pindel, varscan2
- GMEB1 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 109/948 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- GON4L | c.4553A>G p.Q1518R | Missense Mutation (SNP) | VAF 46/410 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GPR158 | c.1393C>A p.L465I | Missense Mutation (SNP) | VAF 19/227 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- GRM8 | c.1721T>C p.I574T | Missense Mutation (SNP) | VAF 22/494 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.339); called by muse, mutect2
- H2BC18 | c.113A>G p.Y38C | Missense Mutation (SNP) | VAF 190/1556 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.633); called by muse, varscan2
- HAO2 | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 71/530 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HERC2 | c.12170_12172del p.E4057del | In Frame Del (DEL) | VAF 76/576 reads (13%) | called by mutect2, pindel, varscan2
- HMOX2 | c.491dup p.Q165Pfs*26 | Frame Shift Ins (INS) | VAF 29/266 reads (11%) | called by mutect2, pindel, varscan2
- HSP90AA1 | c.1352A>G p.E451G | Missense Mutation (SNP) | VAF 100/759 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- HTR3E | c.919dup p.L307Pfs*64 (on ENST00000415389 / NM_001256613.1; = p.L322Pfs*64 on NM_182589.2) | Frame Shift Ins (INS) | VAF 60/534 reads (11%) | called by mutect2, pindel, varscan2
- HYDIN | c.3330G>T p.E1110D | Missense Mutation (SNP) | VAF 44/309 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- HYI | c.199+2T>C p.X67_splice | Splice Site (SNP) | VAF 38/233 reads (16%) | called by muse, mutect2, varscan2
- HYOU1 | c.2400G>T p.E800D | Missense Mutation (SNP) | VAF 107/784 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- ICAM5 | c.1180del p.L394* | Frame Shift Del (DEL) | VAF 58/380 reads (15%) | called by mutect2, pindel, varscan2
- IGLV5-37 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.342); called by muse, mutect2
- INCENP | c.302T>A p.L101H | Missense Mutation (SNP) | VAF 44/448 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2
- INTS12 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2
- IQSEC2 | c.2743C>A p.L915M (on ENST00000642864 / NM_001111125.3; = p.L710M on NM_015075.2) | Missense Mutation (SNP) | VAF 68/635 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IRF3 | c.1156_1158del p.S386del | In Frame Del (DEL) | VAF 40/287 reads (14%) | called by pindel, varscan2
- IRF9 | c.58G>A p.V20M | Missense Mutation (SNP) | VAF 102/711 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KCNA3 | c.609C>A p.F203L | Missense Mutation (SNP) | VAF 37/297 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KCNC3 | c.1dup p.M1? | Frame Shift Ins (INS) | VAF 17/152 reads (11%) | called by pindel, varscan2
- KDM1A | c.672T>G p.N224K | Missense Mutation (SNP) | VAF 33/302 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- KDM2A | c.2412G>T p.Q804H | Missense Mutation (SNP) | VAF 117/1005 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KIDINS220 | c.4930T>C p.S1644P | Missense Mutation (SNP) | VAF 106/977 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF1C | c.1922T>C p.L641P | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- KIF26B | c.5503del p.A1835Pfs*41 | Frame Shift Del (DEL) | VAF 51/319 reads (16%) | called by mutect2, pindel, varscan2
- KLHL25 | c.1016G>A p.G339D | Missense Mutation (SNP) | VAF 66/435 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- KMT2A | c.9932C>T p.A3311V | Missense Mutation (SNP) | VAF 29/480 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); called by muse, mutect2
- LAS1L | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 48/234 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LCE2C | c.56A>G p.K19R | Missense Mutation (SNP) | VAF 61/432 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- LEFTY1 | c.127del p.L43Wfs*15 | Frame Shift Del (DEL) | VAF 38/323 reads (12%) | called by mutect2, pindel, varscan2
- LGALS3BP | c.1484_1486del p.S495del | In Frame Del (DEL) | VAF 94/863 reads (11%) | called by mutect2, pindel, varscan2
- LRP12 | c.1633G>T p.A545S | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- LRRC34 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.059); called by muse, mutect2
- LY75-CD302 | c.5127_5130del p.N1709Kfs*11 | Frame Shift Del (DEL) | VAF 30/301 reads (10%) | called by mutect2, pindel
- MACC1 | c.1838dup p.N613Kfs*16 | Frame Shift Ins (INS) | VAF 42/365 reads (12%) | called by mutect2, pindel, varscan2
- MACC1 | c.296A>C p.D99A | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2
- MCIDAS | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 89/721 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MCM5 | c.2104-2A>C p.X702_splice | Splice Site (SNP) | VAF 35/260 reads (13%) | called by muse, mutect2, varscan2
- MED13 | c.1416del p.L473* | Frame Shift Del (DEL) | VAF 50/509 reads (10%) | called by mutect2, pindel, varscan2
- MED13 | c.693del p.K231Nfs*2 | Frame Shift Del (DEL) | VAF 60/520 reads (12%) | called by mutect2, pindel, varscan2
- MEF2D | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 55/427 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEI1 | c.3056_3058del p.F1019del | In Frame Del (DEL) | VAF 46/476 reads (10%) | called by mutect2, pindel
- MELTF | c.857A>G p.D286G | Missense Mutation (SNP) | VAF 103/832 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- MGAT2 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 37/313 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- MINPP1 | c.1144G>T p.G382C | Missense Mutation (SNP) | VAF 44/443 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MROH8 | c.1181T>C p.L394P | Missense Mutation (SNP) | VAF 48/502 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTF1 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 40/465 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- MTMR4 | c.713T>C p.I238T | Missense Mutation (SNP) | VAF 75/490 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MYO16 | c.4357C>A p.H1453N | Missense Mutation (SNP) | VAF 65/480 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO5C | c.4568A>G p.Q1523R | Missense Mutation (SNP) | VAF 68/446 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by mutect2, varscan2
- MYO6 | c.171del p.D58Mfs*8 | Frame Shift Del (DEL) | VAF 69/588 reads (12%) | called by mutect2, pindel, varscan2
- MYOF | c.500dup p.P169Afs*27 | Frame Shift Ins (INS) | VAF 62/645 reads (10%) | called by mutect2, pindel, varscan2
- MYRF | c.1667A>G p.H556R (on ENST00000278836 / NM_001127392.3; = p.H547R on NM_013279.4) | Missense Mutation (SNP) | VAF 76/778 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.176); called by muse, mutect2
- NAA25 | c.2815_2816del p.K939Dfs*26 | Frame Shift Del (DEL) | VAF 54/542 reads (10%) | called by mutect2, pindel, varscan2
- NAT10 | c.3036_3037del p.E1012Dfs*24 | Frame Shift Del (DEL) | VAF 30/306 reads (10%) | called by pindel, varscan2
- NBAS | c.4714C>T p.Q1572* | Nonsense Mutation (SNP) | VAF 169/796 reads (21%) | called by muse, mutect2, varscan2
- NBEAL2 | c.2308T>C p.S770P | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NCOR2 | c.2609C>T p.A870V | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEPRO | c.993dup p.K332* | Frame Shift Ins (INS) | VAF 30/236 reads (13%) | called by mutect2, pindel, varscan2
- NET1 | c.822A>T p.K274N (on ENST00000355029 / NM_001047160.3; = p.K220N on NM_005863.5) | Missense Mutation (SNP) | VAF 63/453 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- NEURL1 | c.788A>T p.D263V | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- NHSL1 | c.1708dup p.L570Pfs*16 | Frame Shift Ins (INS) | VAF 69/609 reads (11%) | called by mutect2, pindel, varscan2
- NIPBL | c.7742A>G p.N2581S | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.063); called by muse, mutect2
- NKAPL | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 46/366 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NODAL | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 41/498 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOS2 | c.1166A>G p.Y389C | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NT5DC2 | c.1237-8G>A | Splice Region (SNP) | VAF 68/544 reads (13%) | called by muse, mutect2, varscan2
- NYAP2 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OAS3 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 128/1204 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBSCN | c.3268dup p.A1090Gfs*8 | Frame Shift Ins (INS) | VAF 61/555 reads (11%) | called by mutect2, pindel, varscan2
- OR7G2 | c.502C>A p.L168I | Missense Mutation (SNP) | VAF 39/332 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- OTOP3 | c.1726C>A p.L576M | Missense Mutation (SNP) | VAF 44/260 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2
- PARP1 | c.2525A>G p.E842G | Missense Mutation (SNP) | VAF 132/1131 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- PBRM1 | c.4045del p.L1349Wfs*35 | Frame Shift Del (DEL) | VAF 58/333 reads (17%) | called by mutect2, pindel, varscan2
- PCDHB4 | c.431A>T p.N144I | Missense Mutation (SNP) | VAF 77/458 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PCDHB6 | c.434C>A p.T145N | Missense Mutation (SNP) | VAF 171/633 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHGA11 | c.442A>G p.I148V | Missense Mutation (SNP) | VAF 46/466 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2
- PECR | c.104T>G p.V35G | Missense Mutation (SNP) | VAF 133/1049 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- PHACTR3 | c.743dup p.N248Kfs*48 | Frame Shift Ins (INS) | VAF 38/398 reads (10%) | called by mutect2, pindel
- PI15 | c.467A>T p.D156V | Missense Mutation (SNP) | VAF 135/573 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PIANP | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 101/892 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- PIAS4 | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 89/653 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- PIGR | c.2199G>A p.R733= | Splice Region (SNP) | VAF 76/724 reads (10%) | called by muse, mutect2, varscan2
- PITHD1 | c.130A>G p.N44D | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PKD2 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 90/646 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, varscan2
- PLA1A | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 61/455 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PLA2G4E | c.1781C>T p.T594I | Missense Mutation (SNP) | VAF 21/284 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.435); called by muse, mutect2
- PLCG1 | c.1800G>A p.W600* | Nonsense Mutation (SNP) | VAF 69/447 reads (15%) | called by muse, mutect2, varscan2
- PLXDC2 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNA2 | c.4442C>T p.A1481V | Missense Mutation (SNP) | VAF 79/770 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PNPLA7 | c.3863C>T p.S1288L | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); called by muse, mutect2
- POLR2A | c.3488A>G p.H1163R | Missense Mutation (SNP) | VAF 69/456 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- PPP2R3A | c.1922G>A p.R641K | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRCC | c.316del p.E106Rfs*40 | Frame Shift Del (DEL) | VAF 54/374 reads (14%) | called by mutect2, pindel, varscan2
- PRND | c.-11-2A>G | Splice Site (SNP) | VAF 94/1002 reads (9%) | called by muse, mutect2
- PRRX2 | c.350A>G p.Q117R | Missense Mutation (SNP) | VAF 70/491 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- PRSS37 | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 45/319 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PRSS38 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 66/868 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2
- PUDP | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 52/584 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.074); called by muse, mutect2
- PXMP2 | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 60/717 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.334); called by muse, mutect2
- PYROXD1 | c.1411T>C p.F471L | Missense Mutation (SNP) | VAF 75/620 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- QRICH2 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 166/1059 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAI1 | c.4199G>A p.C1400Y | Missense Mutation (SNP) | VAF 116/2043 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- REEP4 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- RIPPLY2 | c.335A>T p.Y112F | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- RMDN3 | c.604T>C p.C202R | Missense Mutation (SNP) | VAF 68/692 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- RNF220 | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 37/297 reads (12%) | called by muse, mutect2, varscan2
- ROBO3 | c.1614G>A p.M538I | Missense Mutation (SNP) | VAF 48/536 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- RPAIN | c.16A>G p.R6G | Missense Mutation (SNP) | VAF 90/882 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPL5 | c.3+8G>A | Splice Region (SNP) | VAF 127/1216 reads (10%) | called by muse, mutect2, varscan2
- RPTOR | c.3932C>T p.P1311L | Missense Mutation (SNP) | VAF 41/363 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RTF1 | c.753dup p.L252Tfs*22 | Frame Shift Ins (INS) | VAF 24/218 reads (11%) | called by mutect2, pindel, varscan2
- RTL1 | c.3619del p.Q1207Rfs*77 | Frame Shift Del (DEL) | VAF 29/244 reads (12%) | called by mutect2, pindel, varscan2
- RTL1 | c.2876A>G p.N959S | Missense Mutation (SNP) | VAF 64/507 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RUVBL1 | c.109T>G p.S37A | Missense Mutation (SNP) | VAF 38/325 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- S100PBP | c.471T>A p.D157E | Missense Mutation (SNP) | VAF 62/487 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- SAMD10 | c.271del p.Q91Rfs*21 | Frame Shift Del (DEL) | VAF 56/444 reads (13%) | called by mutect2, pindel, varscan2
- SCAF8 | c.1333T>C p.S445P | Missense Mutation (SNP) | VAF 59/530 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SCML4 | c.1120_1122del p.E374del | In Frame Del (DEL) | VAF 58/507 reads (11%) | called by mutect2, pindel, varscan2
- SCNN1B | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 119/924 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCRIB | c.2372C>T p.A791V | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2
- SESN2 | c.1004del p.P335Lfs*17 | Frame Shift Del (DEL) | VAF 43/399 reads (11%) | called by mutect2, pindel, varscan2
- SETX | c.961A>G p.N321D | Missense Mutation (SNP) | VAF 54/654 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2
- SF3B4 | c.1060del p.R354Efs*26 | Frame Shift Del (DEL) | VAF 39/240 reads (16%) | called by mutect2, pindel, varscan2
- SHANK3 | c.2451del p.A819Rfs*67 | Frame Shift Del (DEL) | VAF 40/374 reads (11%) | called by mutect2, pindel, varscan2
- SHLD2 | c.1285del p.T429Hfs*3 | Frame Shift Del (DEL) | VAF 23/245 reads (9%) | called by mutect2, varscan2
- SIGLEC11 | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 34/399 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SINHCAF | c.478dup p.S160Ffs*20 | Frame Shift Ins (INS) | VAF 43/205 reads (21%) | called by mutect2, pindel, varscan2
- SLC17A4 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 82/621 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- SLC34A1 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 148/1134 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.762); called by muse, varscan2
- SLC38A1 | c.1406G>A p.S469N | Missense Mutation (SNP) | VAF 42/713 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); called by muse, mutect2
- SLC3A2 | c.1400G>A p.S467N | Missense Mutation (SNP) | VAF 74/612 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- SMARCC1 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 42/275 reads (15%) | called by muse, mutect2, varscan2
- SMCO2 | c.862T>C p.F288L | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.248); called by muse, mutect2
- SOGA3 | c.890dup p.A298Cfs*75 | Frame Shift Ins (INS) | VAF 43/315 reads (14%) | called by mutect2, pindel, varscan2
- SOX6 | c.249T>A p.N83K | Missense Mutation (SNP) | VAF 70/647 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SP8 | c.592G>A p.A198T (on ENST00000361443 / NM_198956.4; = p.A216T on NM_182700.6) | Missense Mutation (SNP) | VAF 59/471 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- SPIRE1 | c.1770dup p.G591Rfs*25 (on ENST00000409402 / NM_001128626.2; = p.G577Rfs*25 on NM_020148.3) | Frame Shift Ins (INS) | VAF 33/261 reads (13%) | called by mutect2, pindel, varscan2
- SPNS2 | c.795G>A p.V265= | Splice Region (SNP) | VAF 105/1072 reads (10%) | called by muse, mutect2
- SPO11 | c.362T>C p.I121T | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.225); called by muse, mutect2
- SPOCK1 | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 38/257 reads (15%) | called by muse, mutect2, varscan2
- SPTBN5 | c.4503G>A p.R1501= | Splice Region (SNP) | VAF 17/151 reads (11%) | called by muse, mutect2
- SRA1 | c.246_249del p.S82Rfs*28 | Frame Shift Del (DEL) | VAF 55/332 reads (17%) | called by mutect2, pindel, varscan2
- SRC | c.770del p.G257Afs*44 | Frame Shift Del (DEL) | VAF 41/388 reads (11%) | called by mutect2, pindel, varscan2
- SRGAP3 | c.2548del p.V850* | Frame Shift Del (DEL) | VAF 267/1592 reads (17%) | called by mutect2, pindel, varscan2
- SRL | c.1188del p.N397Tfs*97 | Frame Shift Del (DEL) | VAF 118/773 reads (15%) | called by mutect2, pindel, varscan2
- SRSF2 | c.581del p.P194Qfs*38 (on ENST00000359995 / NM_001195427.2; = p.P194Qfs*50 on NM_003016.4) | Frame Shift Del (DEL) | VAF 51/371 reads (14%) | called by mutect2, pindel, varscan2
- STK35 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 89/886 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.176); called by muse, mutect2
- SUMF2 | c.640C>A p.L214M (on ENST00000652303; = p.L195M on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TBC1D16 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 82/638 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- THUMPD3 | c.393del p.V132Cfs*18 | Frame Shift Del (DEL) | VAF 13/120 reads (11%) | called by mutect2, pindel, varscan2
- TIAM2 | c.863dup p.P289Afs*32 | Frame Shift Ins (INS) | VAF 94/621 reads (15%) | called by mutect2, pindel, varscan2
- TLR4 | c.827C>T p.A276V (on ENST00000355622 / NM_138554.5; = p.A236V on NM_003266.4) | Missense Mutation (SNP) | VAF 74/728 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR9 | c.2450A>T p.D817V | Missense Mutation (SNP) | VAF 69/500 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TLR9 | c.1862T>C p.L621P | Missense Mutation (SNP) | VAF 104/656 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- TMEM106B | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- TMEM127 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 82/738 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM163 | c.787A>C p.T263P | Missense Mutation (SNP) | VAF 89/542 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- TMEM183A | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 59/738 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- TMEM63A | c.1139A>G p.E380G | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- TMPRSS5 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- TNFRSF10D | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 66/673 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- TNIP1 | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 24/295 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.311); called by muse, mutect2
- TRIL | c.505del p.A169Rfs*34 | Frame Shift Del (DEL) | VAF 58/533 reads (11%) | called by mutect2, pindel, varscan2
- TRIM49C | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 45/648 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- TRMT2A | c.1553C>A p.S518Y | Missense Mutation (SNP) | VAF 85/540 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- TTC39B | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 35/309 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.68114A>G p.K22705R (on ENST00000591111; = p.K15281R on NM_003319.4) | Missense Mutation (SNP) | VAF 33/257 reads (13%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TUT4 | c.1429T>C p.C477R | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- TXNDC16 | c.1030A>C p.I344L | Missense Mutation (SNP) | VAF 42/387 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- UBAP2L | c.305A>G p.K102R | Missense Mutation (SNP) | VAF 105/771 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- UBE3A | c.59A>T p.E20V | Missense Mutation (SNP) | VAF 67/544 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- UBFD1 | c.483A>T p.L161F | Missense Mutation (SNP) | VAF 54/945 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2
- UGT1A8 | c.351del p.F117Lfs*17 | Frame Shift Del (DEL) | VAF 40/376 reads (11%) | called by mutect2, varscan2
- VGLL1 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 102/661 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- VIPR2 | c.909A>G p.I303M | Missense Mutation (SNP) | VAF 56/474 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, varscan2
- VPS13A | c.4073C>T p.A1358V | Missense Mutation (SNP) | VAF 62/728 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- VPS13B | c.3309G>A p.W1103* | Nonsense Mutation (SNP) | VAF 104/1116 reads (9%) | called by muse, mutect2
- VPS45 | c.1454A>C p.N485T | Missense Mutation (SNP) | VAF 29/288 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.015); called by muse, mutect2
- WASHC4 | c.2275A>G p.T759A | Missense Mutation (SNP) | VAF 64/465 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR17 | c.2922+2T>C p.X974_splice | Splice Site (SNP) | VAF 36/307 reads (12%) | called by muse, mutect2, varscan2
- XPO5 | c.1514C>A p.A505D | Missense Mutation (SNP) | VAF 49/472 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- YARS1 | c.1219G>A p.V407I | Missense Mutation (SNP) | VAF 156/608 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- ZBTB32 | c.1268_1269del p.H423Rfs*70 | Frame Shift Del (DEL) | VAF 54/566 reads (10%) | called by pindel, varscan2
- ZBTB41 | c.1870del p.I624Yfs*88 | Frame Shift Del (DEL) | VAF 28/251 reads (11%) | called by mutect2, pindel, varscan2
- ZBTB45 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 78/657 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZC3H4 | c.2890_2892del p.K964del | In Frame Del (DEL) | VAF 20/146 reads (14%) | called by pindel, varscan2
- ZFHX3 | c.6064T>C p.Y2022H | Missense Mutation (SNP) | VAF 129/1049 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ZFHX4 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 92/900 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- ZFHX4 | c.1252A>T p.T418S | Missense Mutation (SNP) | VAF 50/701 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); called by muse, mutect2
- ZKSCAN8 | c.541dup p.Q181Pfs*43 | Frame Shift Ins (INS) | VAF 48/324 reads (15%) | called by mutect2, pindel, varscan2
- ZMPSTE24 | c.524A>G p.Q175R | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ZNF117 | c.1450T>C p.*484Rext*84 | Nonstop Mutation (SNP) | VAF 13/184 reads (7%) | called by muse, mutect2
- ZNF146 | c.304T>C p.C102R | Missense Mutation (SNP) | VAF 53/390 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF345 | c.482T>C p.L161P | Missense Mutation (SNP) | VAF 62/584 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- ZNF366 | c.1430A>G p.Y477C | Missense Mutation (SNP) | VAF 82/328 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF439 | c.1144T>C p.Y382H | Missense Mutation (SNP) | VAF 79/525 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ZNF469 | c.5795G>T p.G1932V (on ENST00000437464; = p.G1960V on NM_001367624.2) | Missense Mutation (SNP) | VAF 48/514 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2
- ZNF48 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 115/908 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF579 | c.107del p.G36Afs*29 | Frame Shift Del (DEL) | VAF 50/300 reads (17%) | called by mutect2, pindel, varscan2
- ZNF628 | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 70/646 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- ZNF776 | c.366del p.K122Nfs*31 | Frame Shift Del (DEL) | VAF 36/298 reads (12%) | called by mutect2, varscan2
- ZNF83 | c.1169A>G p.Q390R | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- ZNRF1 | c.222dup p.A75Rfs*38 | Frame Shift Ins (INS) | VAF 36/368 reads (10%) | called by mutect2, pindel
- AASDH | c.1947C>T p.S649= | Silent (SNP) | VAF 52/359 reads (14%) | catalogued as rs763808403, COSV52708510; called by muse, mutect2, varscan2
- ABCA1 | c.1089G>A p.E363= | Silent (SNP) | VAF 52/748 reads (7%) | catalogued as rs1461964626; called by muse, mutect2
- ABCA7 | c.4465C>A p.R1489= | Silent (SNP) | VAF 67/425 reads (16%) | catalogued as CM1512526; called by muse, mutect2, varscan2
- ABCC8 | c.339G>A p.A113= | Silent (SNP) | VAF 145/1100 reads (13%) | catalogued as rs1161988958; called by muse, mutect2, varscan2
- ADI1 | c.513C>T p.Y171= | Silent (SNP) | VAF 29/348 reads (8%) | catalogued as rs771361700; called by muse, mutect2
- ADPRHL1 | c.549C>A p.A183= | Silent (SNP) | VAF 65/584 reads (11%) | catalogued as COSV62910012; called by muse, mutect2, varscan2
- AGPAT1 | c.217C>T p.L73= | Silent (SNP) | VAF 27/195 reads (14%) | called by muse, mutect2, varscan2
- AIFM3 | c.396C>T p.G132= | Silent (SNP) | VAF 61/585 reads (10%) | catalogued as rs749009581; called by muse, mutect2, varscan2
- AKAP6 | c.1911T>C p.L637= | Silent (SNP) | VAF 75/584 reads (13%) | called by muse, mutect2, varscan2
- AMFR | c.1740C>T p.R580= | Silent (SNP) | VAF 62/471 reads (13%) | called by muse, mutect2, varscan2
- ANKRD52 | c.150C>T p.Y50= | Silent (SNP) | VAF 56/536 reads (10%) | catalogued as rs745548050; called by muse, mutect2
- APCDD1L | c.1104G>A p.T368= | Silent (SNP) | VAF 45/322 reads (14%) | catalogued as rs771870241; called by muse, mutect2, varscan2
- APCDD1L | c.600C>T p.R200= | Silent (SNP) | VAF 32/916 reads (3%) | catalogued as rs1158284668, COSV64487132; called by muse, mutect2
- ASXL3 | c.6060A>G p.P2020= | Silent (SNP) | VAF 50/438 reads (11%) | catalogued as rs369151165; called by muse, mutect2, varscan2
- ATG2A | c.1812C>A p.A604= | Silent (SNP) | VAF 55/364 reads (15%) | catalogued as COSV65968798; called by muse, mutect2, varscan2
- AUTS2 | c.765G>A p.T255= | Silent (SNP) | VAF 56/343 reads (16%) | catalogued as rs758258700, COSV61381280; called by muse, mutect2, varscan2
- BLK | c.900C>T p.Y300= | Silent (SNP) | VAF 45/360 reads (13%) | catalogued as rs139994406; called by muse, mutect2, varscan2
- BMERB1 | c.585T>C p.C195= | Silent (SNP) | VAF 50/348 reads (14%) | called by muse, varscan2
- CABIN1 | c.4650C>T p.R1550= | Silent (SNP) | VAF 62/1203 reads (5%) | catalogued as rs74334271; called by muse, mutect2
- CACNA1C | c.5307C>T p.N1769= | Silent (SNP) | VAF 70/1016 reads (7%) | catalogued as rs530924728, COSV59725170; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- CAMSAP3 | c.2457C>T p.P819= | Silent (SNP) | VAF 95/719 reads (13%) | catalogued as rs747913590; called by muse, mutect2, varscan2
- CASK | c.573C>T p.V191= | Silent (SNP) | VAF 60/347 reads (17%) | called by muse, mutect2, varscan2
- CASKIN1 | c.4269C>T p.A1423= | Silent (SNP) | VAF 71/546 reads (13%) | catalogued as rs764298665; called by muse, mutect2, varscan2
- CAVIN1 | c.651C>T p.R217= | Silent (SNP) | VAF 64/722 reads (9%) | catalogued as rs1181667379; called by muse, mutect2
- CCDC9B | c.285G>A p.E95= | Silent (SNP) | VAF 89/663 reads (13%) | catalogued as rs1225234929; called by muse, mutect2, varscan2
- CD33 | c.327G>A p.R109= | Silent (SNP) | VAF 21/167 reads (13%) | catalogued as COSV99220332; called by muse, mutect2, varscan2
- CDC42BPB | c.4536C>T p.L1512= | Silent (SNP) | VAF 87/797 reads (11%) | catalogued as rs1017268510; called by muse, mutect2, varscan2
- CDH15 | c.558C>T p.N186= | Silent (SNP) | VAF 78/602 reads (13%) | catalogued as rs553396027, COSV57026845; called by muse, mutect2, varscan2
- CEP192 | c.1884A>G p.S628= | Silent (SNP) | VAF 17/198 reads (9%) | catalogued as rs578011977; called by muse, mutect2
- CEP295 | c.4857A>G p.K1619= | Silent (SNP) | VAF 54/516 reads (10%) | catalogued as rs920361291; called by muse, mutect2, varscan2
- CGB5 | c.480C>T p.T160= | Silent (SNP) | VAF 39/498 reads (8%) | called by muse, mutect2, varscan2
- COL8A1 | c.174A>G p.V58= | Silent (SNP) | VAF 121/936 reads (13%) | catalogued as COSV104369388; called by muse, mutect2, varscan2
- COPS2 | c.1215C>T p.V405= | Silent (SNP) | VAF 55/409 reads (13%) | called by muse, mutect2, varscan2
- CPXM1 | c.531C>T p.D177= | Silent (SNP) | VAF 69/497 reads (14%) | catalogued as rs149725071; called by muse, mutect2, varscan2
- CRKL | c.720G>A p.A240= | Silent (SNP) | VAF 76/537 reads (14%) | catalogued as rs755185083; called by muse, mutect2, varscan2
- CRTAC1 | c.795C>T p.N265= | Silent (SNP) | VAF 60/514 reads (12%) | called by muse, mutect2, varscan2
- CYP7B1 | c.93G>T p.L31= | Silent (SNP) | VAF 127/1162 reads (11%) | catalogued as rs1294845737; called by muse, mutect2, varscan2
- DEFB129 | c.348T>C p.F116= | Silent (SNP) | VAF 116/1013 reads (11%) | called by muse, mutect2, varscan2
- DNAH10 | c.4524C>A p.I1508= (on ENST00000409039; = p.I1447= on NM_207437.3) | Silent (SNP) | VAF 92/872 reads (11%) | catalogued as COSV68993698; called by muse, mutect2, varscan2
- DNAH7 | c.10423T>C p.L3475= | Silent (SNP) | VAF 31/382 reads (8%) | catalogued as rs777941465; called by muse, mutect2
- DNAJB7 | c.159C>T p.Y53= | Silent (SNP) | VAF 33/257 reads (13%) | catalogued as rs372594873; called by muse, mutect2, varscan2
- DOCK3 | c.4119C>T p.Y1373= | Silent (SNP) | VAF 24/266 reads (9%) | catalogued as rs531449349, COSV56504016, COSV56506594; called by muse, mutect2
- DOK7 | c.966G>A p.L322= | Silent (SNP) | VAF 76/598 reads (13%) | called by muse, mutect2, varscan2
- DPM1 | c.547T>C p.L183= | Silent (SNP) | VAF 53/509 reads (10%) | called by muse, mutect2, varscan2
- DRGX | c.72T>C p.F24= | Silent (SNP) | VAF 85/757 reads (11%) | called by muse, mutect2, varscan2
- DST | c.6729A>G p.T2243= | Silent (SNP) | VAF 45/361 reads (12%) | catalogued as rs370484930; called by muse, mutect2, varscan2
- EFR3A | c.345T>C p.L115= | Silent (SNP) | VAF 15/194 reads (8%) | called by muse, mutect2
- EIF2B4 | c.816C>T p.S272= (on ENST00000347454 / NM_001034116.2; = p.S271= on NM_015636.3) | Silent (SNP) | VAF 286/1384 reads (21%) | called by muse, mutect2, varscan2
- EIF3B | c.1791C>T p.N597= | Silent (SNP) | VAF 37/230 reads (16%) | catalogued as rs754459941, COSV62804433; called by muse, mutect2, varscan2
- EN2 | c.510C>T p.G170= | Silent (SNP) | VAF 65/770 reads (8%) | catalogued as rs754732993; called by muse, mutect2
- EPHA1 | c.855C>T p.Y285= | Silent (SNP) | VAF 9/128 reads (7%) | called by muse, mutect2
- EPHA5 | c.858C>T p.I286= | Silent (SNP) | VAF 60/393 reads (15%) | catalogued as rs767238890, COSV56628241; called by muse, mutect2, varscan2
- EPHA6 | c.2676C>T p.D892= (on ENST00000389672 / NM_001080448.3; = p.D284= on NM_173655.4) | Silent (SNP) | VAF 64/622 reads (10%) | called by muse, mutect2, varscan2
- ERCC2 | c.513C>T p.P171= | Silent (SNP) | VAF 139/839 reads (17%) | catalogued as rs764710141, COSV99676236; called by muse, mutect2, varscan2
- ERCC6 | c.1197T>A p.G399= | Silent (SNP) | VAF 87/523 reads (17%) | called by muse, mutect2, varscan2
- ERVV-2 | c.702G>A p.S234= | Silent (SNP) | VAF 89/1216 reads (7%) | catalogued as rs1319087087, COSV74153548; called by muse, mutect2
- FAM135B | c.3729C>T p.F1243= | Silent (SNP) | VAF 58/1014 reads (6%) | catalogued as rs1310598121, COSV52708517; called by muse, mutect2
- FAM13B | c.2229G>A p.R743= | Silent (SNP) | VAF 45/319 reads (14%) | catalogued as COSV50369080; called by muse, mutect2, varscan2
- FAM78B | c.124C>T p.L42= | Silent (SNP) | VAF 44/384 reads (11%) | called by muse, mutect2, varscan2
- FASN | c.1182C>G p.G394= | Silent (SNP) | VAF 151/1309 reads (12%) | called by muse, mutect2, varscan2
- FCGBP | c.9195C>T p.C3065= | Silent (SNP) | VAF 142/1638 reads (9%) | catalogued as rs1321951948; called by muse, varscan2
- FGA | c.837C>T p.T279= | Silent (SNP) | VAF 53/335 reads (16%) | catalogued as rs763049586; called by muse, mutect2, varscan2
- FKBP6 | c.66C>T p.Y22= | Silent (SNP) | VAF 102/1412 reads (7%) | catalogued as rs1322846011, COSV52720500; called by muse, mutect2
- FLG2 | c.3273A>G p.Q1091= | Silent (SNP) | VAF 117/1178 reads (10%) | called by muse, mutect2, varscan2
- FOXG1 | c.729G>A p.P243= | Silent (SNP) | VAF 118/783 reads (15%) | catalogued as rs774525510, COSV57395668; ClinVar: likely benign; called by muse, mutect2, varscan2
- FPR2 | c.501A>G p.V167= | Silent (SNP) | VAF 88/787 reads (11%) | called by muse, mutect2, varscan2
- FRMPD2 | c.270A>G p.L90= | Silent (SNP) | VAF 34/288 reads (12%) | called by muse, mutect2, varscan2
- FSBP | c.615G>A p.S205= | Silent (SNP) | VAF 42/474 reads (9%) | catalogued as rs570469619, COSV52594708; called by muse, mutect2
- FTSJ3 | c.867C>T p.D289= | Silent (SNP) | VAF 113/1014 reads (11%) | called by muse, mutect2, varscan2
- GNAT2 | c.972C>A p.T324= | Silent (SNP) | VAF 103/670 reads (15%) | called by muse, mutect2, varscan2
- GPR87 | c.555A>G p.T185= | Silent (SNP) | VAF 70/791 reads (9%) | called by muse, mutect2
- H2AC16 | c.348A>G p.L116= | Silent (SNP) | VAF 17/516 reads (3%) | called by muse, mutect2
- H3C10 | c.9T>C p.R3= | Silent (SNP) | VAF 42/396 reads (11%) | called by muse, mutect2, varscan2
- HGD | c.861A>G p.S287= | Silent (SNP) | VAF 109/951 reads (11%) | catalogued as COSV52196233; called by muse, mutect2, varscan2
- HID1 | c.1266T>C p.G422= | Silent (SNP) | VAF 71/690 reads (10%) | called by muse, mutect2, varscan2
- HSPA12A | c.45G>A p.T15= | Silent (SNP) | VAF 75/645 reads (12%) | catalogued as rs1554882604, COSV65020951, COSV65021134; called by muse, varscan2
- IFFO1 | c.504G>A p.A168= | Silent (SNP) | VAF 80/592 reads (14%) | catalogued as rs1437117217; called by muse, mutect2, varscan2
- IGHA2 | c.219G>A p.P73= | Silent (SNP) | VAF 106/908 reads (12%) | catalogued as rs781958889; called by muse, mutect2, varscan2
- IL18RAP | c.780A>G p.T260= | Silent (SNP) | VAF 31/259 reads (12%) | called by muse, mutect2, varscan2
- IRF2BP1 | c.1464G>T p.G488= | Silent (SNP) | VAF 74/522 reads (14%) | catalogued as rs749307369; called by muse, mutect2, varscan2
- IZUMO2 | c.198G>T p.R66= | Silent (SNP) | VAF 32/297 reads (11%) | called by muse, mutect2, varscan2
- KBTBD11 | c.1371C>T p.G457= | Silent (SNP) | VAF 95/540 reads (18%) | catalogued as rs1393661676; called by muse, mutect2, varscan2
- KCNA3 | c.240C>T p.G80= | Silent (SNP) | VAF 36/579 reads (6%) | catalogued as rs1369854327; called by muse, mutect2
- KCNJ4 | c.556C>T p.L186= | Silent (SNP) | VAF 70/454 reads (15%) | called by muse, mutect2, varscan2
- KCTD11 | c.180C>T p.G60= (on ENST00000333751 / NM_001363642.1; = p.G21= on NM_001002914.2) | Silent (SNP) | VAF 38/241 reads (16%) | catalogued as rs771444276; called by muse, mutect2, varscan2
- KHDRBS2 | c.72G>A p.A24= | Silent (SNP) | VAF 52/354 reads (15%) | called by muse, mutect2, varscan2
- KIF17 | c.1338C>T p.D446= | Silent (SNP) | VAF 100/662 reads (15%) | catalogued as rs765789636; called by muse, mutect2, varscan2
- KIF5C | c.243G>A p.T81= | Silent (SNP) | VAF 57/522 reads (11%) | catalogued as rs186518670; called by muse, mutect2, varscan2
- KLHDC7B | c.456G>T p.G152= (on ENST00000395676; = p.G793= on NM_138433.5) | Silent (SNP) | VAF 42/261 reads (16%) | called by muse, mutect2, varscan2
- KLK4 | c.495G>A p.L165= | Silent (SNP) | VAF 154/1213 reads (13%) | called by muse, mutect2, varscan2
- KRT20 | c.186C>T p.G62= | Silent (SNP) | VAF 76/534 reads (14%) | catalogued as rs1488312655; called by muse, mutect2, varscan2
- KRT6A | c.9C>T p.S3= | Silent (SNP) | VAF 334/1608 reads (21%) | called by muse, mutect2, varscan2
- KRTAP5-2 | c.81C>T p.G27= | Silent (SNP) | VAF 40/339 reads (12%) | called by mutect2, varscan2
- KY | c.1125C>T p.C375= | Silent (SNP) | VAF 22/215 reads (10%) | catalogued as rs759535501, COSV71018403; called by muse, mutect2, varscan2
- LDHA | c.990G>A p.L330= | Silent (SNP) | VAF 86/668 reads (13%) | catalogued as rs558872434; called by muse, mutect2, varscan2
- LEUTX | c.31C>T p.L11= | Silent (SNP) | VAF 59/341 reads (17%) | called by muse, mutect2, varscan2
- LHPP | c.594C>A p.A198= | Silent (SNP) | VAF 26/902 reads (3%) | called by muse, mutect2
- LHX3 | c.945C>T p.Y315= (on ENST00000371748 / NM_178138.6; = p.Y320= on NM_014564.5) | Silent (SNP) | VAF 32/237 reads (14%) | catalogued as rs1357275975; called by muse, mutect2, varscan2
- LRP1 | c.1065G>A p.G355= | Silent (SNP) | VAF 164/734 reads (22%) | catalogued as rs747547972; called by muse, mutect2, varscan2
- LRRTM2 | c.522A>G p.V174= | Silent (SNP) | VAF 116/471 reads (25%) | called by muse, mutect2, varscan2
- LTBP4 | c.4683C>T p.D1561= (on ENST00000308370 / NM_001042544.1; = p.D1524= on NM_003573.2) | Silent (SNP) | VAF 80/585 reads (14%) | catalogued as rs1365889140; ClinVar: likely benign; called by muse, mutect2, varscan2
- LYPD5 | c.231C>T p.C77= (on ENST00000377950 / NM_001031749.3; = p.C34= on NM_182573.2) | Silent (SNP) | VAF 58/413 reads (14%) | called by muse, mutect2, varscan2
- LYST | c.39G>C p.L13= | Silent (SNP) | VAF 65/412 reads (16%) | called by muse, mutect2, varscan2
- MAD1L1 | c.2055C>A p.T685= | Silent (SNP) | VAF 57/547 reads (10%) | catalogued as rs377713158; called by muse, mutect2, varscan2
- MICALL2 | c.1029C>T p.S343= | Silent (SNP) | VAF 38/286 reads (13%) | called by muse, mutect2, varscan2
- MKI67 | c.7896A>G p.T2632= | Silent (SNP) | VAF 123/1014 reads (12%) | called by mutect2, varscan2
- MOB2 | c.237G>A p.T79= | Silent (SNP) | VAF 59/502 reads (12%) | catalogued as rs1351803509, COSV57318292; called by muse, mutect2, varscan2
- MTM1 | c.1131C>T p.D377= | Silent (SNP) | VAF 112/824 reads (14%) | catalogued as rs1557414507, COSV100080658; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYBPC3 | c.1815C>T p.D605= | Silent (SNP) | VAF 36/431 reads (8%) | catalogued as rs768380030, COSV57029575; ClinVar: likely benign; called by muse, mutect2
- MYH7B | c.4536G>A p.Q1512= | Silent (SNP) | VAF 35/305 reads (11%) | called by muse, mutect2, varscan2
- MYO18B | c.4344T>C p.D1448= | Silent (SNP) | VAF 38/550 reads (7%) | catalogued as rs1296503471; called by muse, mutect2
- NAA80 | c.576G>A p.E192= (on ENST00000417393 / NM_001200018.2; = p.E214= on NM_012191.4) | Silent (SNP) | VAF 23/182 reads (13%) | catalogued as rs1391162709; called by muse, mutect2, varscan2
- NDST1 | c.1989C>A p.P663= | Silent (SNP) | VAF 94/778 reads (12%) | called by muse, mutect2, varscan2
- NEUROG3 | c.6G>A p.T2= | Silent (SNP) | VAF 40/310 reads (13%) | called by muse, mutect2, varscan2
- NOTCH1 | c.4473G>A p.T1491= | Silent (SNP) | VAF 93/1166 reads (8%) | catalogued as rs941691193, COSV53056929; called by muse, mutect2
- NT5C1B | c.708G>A p.S236= (on ENST00000359846 / NM_001199086.2; = p.S176= on NM_033253.4) | Silent (SNP) | VAF 48/376 reads (13%) | catalogued as COSV100410238; called by muse, mutect2, varscan2
- NTN4 | c.981C>T p.N327= | Silent (SNP) | VAF 40/359 reads (11%) | catalogued as rs374055562, COSV59219495; called by muse, mutect2, varscan2
- OBSCN | c.13833C>A p.P4611= | Silent (SNP) | VAF 45/411 reads (11%) | catalogued as COSV52758050; called by muse, mutect2, varscan2
- OLFM2 | c.198G>A p.R66= | Silent (SNP) | VAF 55/465 reads (12%) | catalogued as rs751745664; called by muse, mutect2, varscan2
- OR1K1 | c.426C>T p.C142= | Silent (SNP) | VAF 67/529 reads (13%) | catalogued as rs780396929, COSV52956460; called by muse, mutect2, varscan2
- OR4D10 | c.171G>A p.T57= | Silent (SNP) | VAF 40/244 reads (16%) | catalogued as rs765052417, COSV101597011; called by muse, mutect2, varscan2
- OR8S1 | c.1062G>A p.A354= | Silent (SNP) | VAF 40/290 reads (14%) | catalogued as rs1480531577, COSV59600243; called by muse, mutect2
- OSCP1 | c.603G>A p.P201= (on ENST00000356637 / NM_001330493.1; = p.P191= on NM_145047.5) | Silent (SNP) | VAF 85/604 reads (14%) | catalogued as rs146439686, COSV99347582; called by muse, mutect2, varscan2
- PAEP | c.489G>A p.R163= | Silent (SNP) | VAF 43/334 reads (13%) | catalogued as rs749179379; called by muse, mutect2, varscan2
- PAPPA | c.1200G>A p.V400= | Silent (SNP) | VAF 68/855 reads (8%) | called by muse, mutect2
- PAQR6 | c.558A>G p.T186= (on ENST00000292291 / NM_001272108.2; = p.T80= on NM_024897.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 105/743 reads (14%) | called by muse, mutect2, varscan2
- PER1 | c.3111C>T p.S1037= | Silent (SNP) | VAF 53/397 reads (13%) | catalogued as rs375292406; called by muse, mutect2, varscan2
- PHKA1 | c.3465G>A p.V1155= | Silent (SNP) | VAF 72/517 reads (14%) | catalogued as rs1262683844; called by muse, mutect2, varscan2
- PIK3CG | c.855G>A p.T285= | Silent (SNP) | VAF 103/814 reads (13%) | catalogued as rs144765743; called by muse, mutect2, varscan2
- PITPNM2 | c.1368C>T p.F456= | Silent (SNP) | VAF 283/1282 reads (22%) | catalogued as rs971868992, COSV54898816; called by muse, mutect2, varscan2
- PLEC | c.2658C>T p.Y886= (on ENST00000322810 / NM_201380.4; = p.Y776= on NM_000445.5) | Silent (SNP) | VAF 47/1780 reads (3%) | catalogued as rs782320325; called by muse, mutect2
- POLH | c.1947A>G p.E649= | Silent (SNP) | VAF 33/234 reads (14%) | called by muse, mutect2, varscan2
- PPP1R3F | c.21G>A p.V7= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs1459652793; called by muse, mutect2, varscan2
- PPP6R2 | c.1476G>A p.E492= | Silent (SNP) | VAF 24/166 reads (14%) | catalogued as rs765723793; called by muse, varscan2
- PRSS23 | c.927C>T p.C309= | Silent (SNP) | VAF 99/629 reads (16%) | catalogued as rs922808925; called by muse, mutect2, varscan2
185 further variants in this file (0 protein-altering or splice-affecting, 58 silent, 127 other) are not listed here.
